Gene-level copy-number profile of tumor specimen HCM-BROD-0418-C71-01A from HCMI case HCM-BROD-0418-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 45.5 years (16,625 days).
Specimen HCM-BROD-0418-C71-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 700ef904-6d31-4bc4-818d-753e23a1c2a9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0418-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/a60a8aba-c864-4a45-9d5f-ead502bc1f85

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 76; copy number 1: 8,201; copy number 2: 44,562; copy number 3: 3,093; copy number 4: 2,906; copy number 5: 7; copy number 8: 3; copy number 20: 2; copy number 21: 33; copy number 23: 19; copy number 105: 6.

Homozygous deletions (total copy number 0; autosomes only): 76 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,331,446–22,214,672, 65 genes (broad region; genes not listed).
- chr9:41,700,480–41,701,096, 2 genes: AL591926.1, AL591926.4.
- chr15:34,379,068–34,521,791, 8 genes: GOLGA8A, MIR1233-1, AC025678.1, AC025678.2, AC025678.3, HNRNPLP2, FSCN1P1, DNM1P5.
- chr15:34,528,290–34,528,371, 1 gene (within-gene range 0–1): MIR1233-2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 70 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:71,075,564–72,403,143, 19 genes, copy number 23 (within-gene range 1–23): BECN1P2, U3, LYPLA1P3, RNU6-411P, AL589935.1, AL589935.3, AL589935.2, OGFRL1, AL136164.2, AL136164.1, LINC00472, MIR30C2, AL136164.3, MIR30A, LINC01626, AL035467.1, KRT19P1, RNU4-66P, RIMS1.
- chr7:54,752,250–55,572,988, 11 genes, copy number 8–105: SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1.
- chr7:76,510,525–76,627,982, 7 genes, copy number 5: UPK3B, AC004980.4, Y_RNA, AC004980.3, SPDYE16, AC004980.1, POMZP3.
- chr9:22,446,824–27,104,728, 33 genes, copy number 21: DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL365204.1, AL365204.2, AL365204.3, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, TUSC1, LINC01241, FAM71BP1, AL353753.1, AL442639.1, AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1.

Autosomal genes at a single copy (total copy number 1): 5,345. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
